Somatic mutation profile of tumor specimen TCGA-A2-A3KD-01A (aliquot TCGA-A2-A3KD-01A-12D-A20S-09) from TCGA case TCGA-A2-A3KD, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 47.6 years (17,372 days).
Specimen TCGA-A2-A3KD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0a719b1-a60b-40d9-a64c-ab59b67729c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A3KD-10A (Blood Derived Normal), aliquot TCGA-A2-A3KD-10A-01D-A20S-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dd3d5f2e-7144-46cb-8977-327157cafcee

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 6, Silent 3, Translation Start Site 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CXCR3 | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1236384823, COSV65461571; called by muse, mutect2, varscan2
- DGKG | c.2277+2T>C p.X759_splice | Splice Site (SNP) | VAF 12/45 reads (27%) | catalogued as COSV53961872; called by muse, mutect2, varscan2
- LMCD1 | c.1046T>C p.V349A | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV50087341; called by muse, mutect2, varscan2
- OR6K6 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 8/75 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV63743648; called by muse, mutect2
- SLC7A14 | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371104588; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF275 | c.1076G>A p.R359H (on ENST00000650114 / NM_001367757.1; = p.P326= on NM_001080485.3) | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV64704099; called by muse, mutect2, varscan2
- IGHA2 | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- SYF2 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.013); called by muse, mutect2
- FOXI1 | c.606C>T p.N202= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV60388045; called by muse, mutect2, varscan2
- HPS4 | c.372C>T p.S124= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV61102615; called by muse, mutect2, varscan2
- SLC39A9 | c.462C>T p.V154= | Silent (SNP) | VAF 33/79 reads (42%) | catalogued as COSV50362050; called by muse, mutect2, varscan2
